Somatic mutation profile of tumor specimen TCGA-GN-A269-01A (aliquot TCGA-GN-A269-01A-11D-A19A-08) from TCGA case TCGA-GN-A269, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Superficial spreading melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 70.0 years (25,583 days).
Specimen TCGA-GN-A269-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2b5bdcf-b839-4166-8bd9-49056c1570bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A269-10A (Blood Derived Normal), aliquot TCGA-GN-A269-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a40bd2f1-8143-4c3b-9a69-400585d1f23a

The open-access MAF lists 897 somatic variants for this specimen: 559 protein-altering or splice-affecting, 310 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 511, Silent 310, Nonsense Mutation 31, Intron 11, Splice Site 9, RNA 8, Splice Region 6, 5'UTR 3, 5'Flank 3, 3'UTR 2, Translation Start Site 1, 3'Flank 1.

Variants (750 of 897; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C8B | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as rs140813121, CM952411, COSV64778579; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- ETV6 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV67149820; called by muse, mutect2, varscan2
- H3C3 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 14/86 reads (16%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV63550964, COSV63551270; called by muse, mutect2, varscan2
- A2ML1 | c.1503G>A p.M501I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV55287583, COSV55294767; called by muse, mutect2, varscan2
- ABCA12 | c.3826C>T p.P1276S (on ENST00000272895 / NM_173076.3; = p.P958S on NM_015657.3) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55967730, COSV99790257; called by muse, varscan2
- ABCB5 | c.2489C>T p.S830F (on ENST00000404938 / NM_001163941.2; = p.S385F on NM_178559.6) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866781790, COSV51705583; called by muse, mutect2, varscan2
- ABCC11 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV62324625; called by muse, mutect2, varscan2
- ABCC9 | c.3895C>T p.P1299S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53979058; called by muse, mutect2, varscan2
- ABCG8 | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 79/507 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV55394952, COSV55397448; called by muse, mutect2, varscan2
- AC011462.1 | c.254A>T p.K85M | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV54198517; called by muse, mutect2, varscan2
- AC100868.1 | c.1640G>A p.R547K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.688); catalogued as COSV51838201; called by muse, mutect2, varscan2
- ACACB | c.4732G>A p.V1578M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58140380; called by muse, mutect2, varscan2
- ACCSL | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV66581989; called by muse, mutect2, varscan2
- ADAD1 | c.640A>T p.K214* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV56645383; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV56476432; called by muse, mutect2
- ADAMTS6 | c.472A>G p.I158V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV66862243; called by muse, mutect2
- ADCYAP1R1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.025); catalogued as rs1307857192, COSV100416360, COSV58441241; called by muse, mutect2, varscan2
- AFF3 | c.2390C>T p.S797F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV57863012; called by muse, mutect2, varscan2
- AGFG2 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV53546244, COSV53547566; called by muse, mutect2, varscan2
- AK5 | c.1634G>T p.G545V (on ENST00000354567 / NM_174858.3; = p.G519V on NM_012093.4) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.251); catalogued as COSV60977381; called by muse, mutect2
- AKAP11 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50298902; called by muse, mutect2, varscan2
- AKAP3 | c.456C>G p.N152K | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57418551; called by muse, mutect2, varscan2
- AKAP6 | c.6727G>A p.E2243K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV55223043; called by muse, mutect2, varscan2
- AL645922.1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs961046350, COSV54961631; called by muse, mutect2
- ALB | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs80008208, CM900010, COSV55740986; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- ALDH9A1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.59); catalogued as rs976703538, COSV61340516; called by muse, mutect2, varscan2
- ALDOB | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV66398272; called by muse, mutect2, varscan2
- ALPI | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs151137290; called by muse, mutect2, varscan2
- ALPK2 | c.1409G>A p.R470K | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs1043484388, COSV64494844; called by muse, mutect2, varscan2
- ANAPC1 | c.5296G>A p.E1766K | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs1417055822, COSV100594494; called by mutect2, varscan2
- ANK1 | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV55888045; called by muse, mutect2, varscan2
- ANK3 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867574111, COSV55069934; called by muse, mutect2, varscan2
- ANKRD30A | c.836G>A p.G279E (on ENST00000611781; = p.G223E on NM_052997.2) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.994); catalogued as COSV64609857; called by muse, mutect2, varscan2
- ANO4 | c.2042G>A p.R681Q (on ENST00000392977 / NM_001286615.2; = p.R646Q on NM_178826.4) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as rs774283498, COSV54603606; called by muse, varscan2
- ANO4 | c.2148G>A p.M716I (on ENST00000392977 / NM_001286615.2; = p.M681I on NM_178826.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs200042629, COSV100151246; called by muse, varscan2
- AOPEP | c.1849C>T p.H617Y (on ENST00000375315 / NM_001193329.1; = p.H518Y on NM_032823.5) | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52994789; called by muse, mutect2, varscan2
- APC | c.6497G>A p.R2166Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.47); catalogued as rs752091655, COSV57330115, COSV57362971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARMH3 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV60750691, COSV60751300; called by muse, mutect2, varscan2
- ARSK | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV66170093; called by muse, mutect2, varscan2
- ASAH2 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 56/267 reads (21%) | catalogued as rs1413048671; called by muse, mutect2, varscan2
- ASPM | c.9592C>T p.R3198C | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as rs760292134, COSV54126456; called by muse, mutect2, varscan2
- ATF7IP2 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV61094411; called by muse, mutect2, varscan2
- ATP11A | c.162+1G>A p.X54_splice | Splice Site (SNP) | VAF 37/109 reads (34%) | catalogued as COSV52117564; called by muse, mutect2, varscan2
- ATP13A4 | c.1522G>A p.G508S | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.048); catalogued as rs758473710, COSV55072299; called by muse, mutect2
- ATP4A | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs775448586, COSV52865136; called by muse, mutect2, varscan2
- ATP7B | c.1987C>T p.P663S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54434792; called by muse, mutect2
- BCAR3 | c.1237C>T p.L413F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV53077098; called by muse, mutect2, varscan2
- BLNK | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV56414349; called by muse, mutect2
- BMT2 | c.935A>T p.H312L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51778701, COSV51779109; called by muse, varscan2
- BOD1L1 | c.4100C>T p.P1367L | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV50029143; called by muse, mutect2, varscan2
- BPIFB2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199805090, COSV50067812; called by muse, mutect2, varscan2
- BPTF | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58842009; called by muse, mutect2, varscan2
- BRAT1 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.383); catalogued as rs1446689584, COSV61396389; called by muse, varscan2
- BRINP3 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.086); catalogued as COSV66515887; called by muse, mutect2, varscan2
- BTF3 | c.272C>T p.S91F (on ENST00000380591 / NM_001037637.1; = p.S47F on NM_001207.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV60063644; called by muse, mutect2
- BTNL3 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV61565294; called by muse, mutect2, varscan2
- BVES | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV58948899; called by muse, mutect2, varscan2
- C1S | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs1555162888, COSV61071510; called by muse, mutect2, varscan2
- C1orf158 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV55347353; called by muse, mutect2, varscan2
- C1orf87 | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64597932; called by muse, mutect2, varscan2
- C2orf80 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs779428333, COSV58017850; called by muse, mutect2, varscan2
- C2orf80 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs138681111, COSV58017866; called by muse, mutect2, varscan2
- C3 | c.3911G>A p.S1304N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55576982; called by muse, mutect2, varscan2
- CA1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.185); catalogued as rs1395135419, COSV56279318; called by muse, mutect2, varscan2
- CA10 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV53358512; called by muse, mutect2, varscan2
- CACNA1D | c.5953C>T p.P1985S (on ENST00000350061 / NM_001128840.3; = p.P2005S on NM_000720.4) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV99856262; called by muse, mutect2, varscan2
- CACNA1D | c.5954C>T p.P1985L (on ENST00000350061 / NM_001128840.3; = p.P2005L on NM_000720.4) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.245); catalogued as COSV99856264; called by muse, mutect2, varscan2
- CACNA2D3 | c.2351C>T p.S784L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as rs751135855, COSV55560446; called by muse, mutect2, varscan2
- CACNB2 | c.1075G>A p.E359K (on ENST00000324631 / NM_201596.3; = p.E304K on NM_000724.4) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV56633541; called by muse, mutect2, varscan2
- CACNG3 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV50069569; called by muse, mutect2
- CACNG6 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as rs1267579555, COSV53167414; called by muse, mutect2, varscan2
- CACNG7 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV55813831; called by muse, mutect2, varscan2
- CAPN10 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as rs760362038, COSV54376964; called by muse, mutect2, varscan2
- CARMIL3 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.074); catalogued as rs781530262, COSV57727508; called by muse, mutect2, varscan2
- CCDC157 | c.1946G>A p.G649E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as rs1205624099, COSV53176593; called by muse, mutect2, varscan2
- CCDC158 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.191); catalogued as COSV63092521; called by muse, mutect2, varscan2
- CCDC73 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV58801594; called by muse, mutect2, varscan2
- CCNA1 | c.417G>A p.M139I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV55222852; called by muse, mutect2, varscan2
- CCNB3 | c.4054G>A p.D1352N | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV52073862; called by muse, mutect2, varscan2
- CCT8L2 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV63463207; called by muse, varscan2
- CCT8L2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs148171132; called by muse, varscan2
- CD163 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as rs267603679, COSV63132851; called by muse, mutect2, varscan2
- CD53 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV54762340, COSV99068362; called by muse, mutect2, varscan2
- CDH12 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66392741; called by muse, mutect2, varscan2
- CDH5 | c.2108G>A p.G703E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.976); catalogued as COSV58518775; called by muse, mutect2, varscan2
- CDH9 | c.1975T>C p.Y659H | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1338719800, COSV50345290; called by muse, mutect2, varscan2
- CDK19 | c.569T>A p.L190* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV60451299; called by muse, mutect2, varscan2
- CDR1 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.01); catalogued as COSV65164506; called by muse, mutect2, varscan2
- CDRT1 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as rs1194429085, COSV55412598; called by muse, mutect2, varscan2
- CELSR3 | c.9233G>A p.R3078Q | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.416); catalogued as rs763972908, COSV50933885, COSV99373741; called by muse, mutect2, varscan2
- CENPE | c.4256T>C p.I1419T | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as rs756176401, COSV54384851; called by muse, mutect2, varscan2
- CEP126 | c.2794C>T p.P932S | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.209); catalogued as COSV54828110; called by muse, varscan2
- CEP72 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV53794965, COSV99374568; called by muse, mutect2
- CEP76 | c.1698T>G p.F566L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50867893; called by muse, mutect2, varscan2
- CFAP43 | c.4583G>A p.R1528K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV63854015; called by muse, mutect2, varscan2
- CFAP70 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs751280782, COSV60285224; called by muse, mutect2, varscan2
- CILK1 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs1199917341, COSV63155260; called by muse, mutect2, varscan2
- CLGN | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57775644; called by muse, mutect2, varscan2
- CLSTN1 | c.845C>T p.A282V (on ENST00000377298 / NM_001009566.3; = p.A272V on NM_014944.4) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as COSV63649672; called by muse, mutect2, varscan2
- CNOT4 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59655715; called by muse, mutect2, varscan2
- CNTN5 | c.1591C>T p.L531F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV54334048; called by muse, mutect2, varscan2
- CNTNAP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.189); catalogued as rs777884519, CM1313256, COSV62148925; called by muse, mutect2, varscan2
- CNTNAP2 | c.1684C>T p.H562Y | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs749273471, COSV62220787; called by muse, mutect2, varscan2
- COL12A1 | c.4240C>T p.R1414* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV59392176; called by muse, mutect2, varscan2
- COL22A1 | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57331125; called by muse, mutect2, varscan2
- COL28A1 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV68083437, COSV99063603; called by muse, mutect2, varscan2
- COL4A1 | c.3535C>T p.P1179S | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV65428746; called by muse, mutect2, varscan2
- COL4A1 | c.2570C>T p.S857L | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.661); catalogued as rs145861489; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.4966C>T p.Q1656* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV55098980; called by muse, mutect2, varscan2
- COL9A1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV57888180; called by muse, mutect2, varscan2
- COQ3 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.759); catalogued as COSV54640929; called by muse, mutect2, varscan2
- COQ8B | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54687970; called by muse, mutect2, varscan2
- CPM | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58034614; called by muse, mutect2, varscan2
- CR2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65506103; called by muse, mutect2
- CRACDL | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV67409298; called by muse, mutect2, varscan2
- CRTAC1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); catalogued as rs775042630, COSV54005438; called by muse, mutect2
- CSMD1 | c.8767G>A p.D2923N (on ENST00000520002; = p.D2922N on NM_033225.6) | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV59351866; called by muse, mutect2, varscan2
- CSMD1 | c.3364C>T p.P1122S (on ENST00000520002; = p.P1121S on NM_033225.6) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59351885; called by muse, mutect2, varscan2
- CSMD2 | c.9830C>T p.S3277F | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53935568; called by muse, mutect2, varscan2
- CSMD2 | c.9680C>T p.S3227F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53935596; called by muse, mutect2, varscan2
- CSMD2 | c.5988G>A p.W1996* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV53881000; called by muse, mutect2
- CSN2 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs754463985, COSV100778701; called by mutect2, varscan2
- CSTF2T | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs373436302; called by muse, mutect2, varscan2
- CTCFL | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs899433950, COSV54773956; called by muse, mutect2, varscan2
- CTNNA2 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.348); catalogued as COSV63584920; called by muse, mutect2, varscan2
- CTNNA2 | c.2816C>T p.S939L (on ENST00000402739 / NM_001282597.3; = p.S891L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs1052098013, COSV58132864; called by muse, mutect2, varscan2
- CXCR5 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV52687091; called by muse, mutect2, varscan2
- CYP2A13 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57837622; called by muse, mutect2, varscan2
- CYP2C19 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV64908586; called by muse, mutect2, varscan2
- CYP2D6 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1135830, COSV62244767; called by muse, mutect2, varscan2
- CYP4A11 | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV60224482; called by muse, mutect2, varscan2
- DAB2 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1282305948, COSV57916793; called by muse, mutect2, varscan2
- DCAF1 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as rs1024548983, COSV60044934; called by muse, mutect2, varscan2
- DCC | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59118613; called by muse, mutect2, varscan2
- DCDC1 | c.5147C>A p.P1716Q (on ENST00000597505 / NM_001367979.1; = p.P823Q on NM_020869.3) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV58001024; called by mutect2, varscan2
- DEFA4 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.37); PolyPhen probably damaging (1); catalogued as COSV52404561; called by muse, mutect2, varscan2
- DGCR2 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs558936135, COSV54220042; called by muse, mutect2, varscan2
- DGKZ | c.1214G>A p.S405N (on ENST00000454345 / NM_001105540.2; = p.S217N on NM_003646.4) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1361878514, COSV58991826; called by muse, mutect2, varscan2
- DKK2 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53400437; called by muse, mutect2, varscan2
- DNAH5 | c.12121C>T p.P4041S | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs1169918695, COSV54239713; called by muse, mutect2, varscan2
- DNAH5 | c.3862G>A p.G1288R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54239721; called by muse, mutect2
- DNAH5 | c.3490C>A p.P1164T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99443610; called by muse, mutect2, varscan2
- DNAH5 | c.2977T>G p.F993V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV54239729; called by muse, mutect2, varscan2
- DNAH5 | c.192G>A p.Q64= | Splice Region (SNP) | VAF 7/72 reads (10%) | catalogued as COSV54239736; called by muse, mutect2
- DNAH9 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52335519; called by muse, mutect2, varscan2
- DNHD1 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 19/164 reads (12%) | catalogued as COSV54440164; called by muse, mutect2, varscan2
- DOCK2 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV56972908; called by muse, mutect2, varscan2
- DOCK8 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369052464; called by muse, mutect2, varscan2
- DPYSL5 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV56514314; called by muse, mutect2, varscan2
- DSC1 | c.2602C>T p.R868W | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs201568166; called by muse, mutect2, varscan2
- DYNC2I1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV68106006; called by muse, mutect2, varscan2
- EGFLAM | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868504934, COSV59310361; called by muse, mutect2, varscan2
- EGFR | c.701A>G p.N234S | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV51823432; called by muse, mutect2, varscan2
- ELAPOR2 | c.3077C>T p.S1026F (on ENST00000450689 / NM_001142749.3; = p.S859F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs747623809, COSV51888492; called by muse, mutect2, varscan2
- ELFN2 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101297570, COSV68745145; called by muse, mutect2, varscan2
- EMC8 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53666269; called by muse, mutect2
- ENOX1 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54908507; called by muse, mutect2, varscan2
- EPHX4 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64889778; called by muse, varscan2
- EPM2AIP1 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV51621310; called by muse, mutect2, varscan2
- EPPK1 | c.5453G>A p.G1818E | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV73261962; called by muse, mutect2, varscan2
- ERICH3 | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV58612134, COSV58612762; called by muse, mutect2, varscan2
- F5 | c.4618G>A p.E1540K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV63126128; called by muse, mutect2, varscan2
- FAAH2 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66510075; called by muse, mutect2, varscan2
- FAM135B | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as rs767926989, COSV52705951; called by muse, mutect2, varscan2
- FAM71A | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54236372; called by muse, mutect2, varscan2
- FAM83C | c.2072G>A p.G691E | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs1416434877, COSV65583754; called by muse, mutect2, varscan2
- FAM83G | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1445162570, COSV58758875; called by muse, mutect2, varscan2
- FANCD2 | c.3667T>C p.F1223L | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV55042182; called by muse, mutect2, varscan2
- FANCG | c.84G>A p.K28= | Splice Region (SNP) | VAF 27/122 reads (22%) | catalogued as COSV66213962; called by muse, mutect2, varscan2
- FANCI | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55530633; called by muse, mutect2, varscan2
- FAT3 | c.12622C>T p.P4208S | Missense Mutation (SNP) | VAF 83/418 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV53144962; called by muse, mutect2, varscan2
- FAT4 | c.4735C>T p.R1579C | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs372570229; called by muse, mutect2, varscan2
- FAT4 | c.9126G>A p.W3042* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV58698056; called by muse, mutect2, varscan2
- FBN3 | c.4468G>A p.G1490R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749506818, COSV54466649, COSV99559663; called by muse, mutect2, varscan2
- FBN3 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV54466662; called by muse, mutect2, varscan2
- FCRL4 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 80/404 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54864083; called by muse, mutect2, varscan2
- FER1L6 | c.3400C>T p.H1134Y | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as COSV67549957; called by muse, mutect2, varscan2
- FGB | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.675); catalogued as COSV57419007; called by muse, mutect2, varscan2
- FLG | c.9577A>G p.R3193G | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV64244946; called by muse, mutect2, varscan2
- FLG | c.7558G>A p.D2520N | Missense Mutation (SNP) | VAF 89/398 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs866141505, COSV64236630; called by muse, mutect2, varscan2
- FLG2 | c.6433G>A p.G2145R | Missense Mutation (SNP) | VAF 92/414 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.233); catalogued as COSV66170864; called by muse, mutect2, varscan2
- FLG2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as COSV66166901; called by muse, mutect2, varscan2
- FLRT2 | c.1181G>A p.S394N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV58146359; called by muse, mutect2, varscan2
- FRAS1 | c.1705G>A p.G569S | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as COSV53628782; called by muse, mutect2, varscan2
- FSHR | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.989); catalogued as CM080377, COSV58628995; called by muse, mutect2, varscan2
- FSIP2 | c.20668C>T p.Q6890* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as rs1476585630, COSV58092896; called by muse, mutect2, varscan2
- FYN | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV57612610, COSV57617681, COSV57618360; called by muse, mutect2, varscan2
- GABRB3 | c.1151G>A p.G384D | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.201); catalogued as COSV54674126; called by muse, mutect2, varscan2
- GABRG1 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777212; called by mutect2, varscan2
- GABRQ | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV64781024; called by muse, mutect2, varscan2
- GALNT8 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV52899378; called by muse, varscan2
- GALNTL6 | c.1626G>A p.W542* | Nonsense Mutation (SNP) | VAF 28/154 reads (18%) | catalogued as COSV72492203; called by muse, varscan2
- GAS2L2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs1342756079; called by muse, mutect2, varscan2
- GCNT1 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV65058216; called by muse, mutect2, varscan2
- GDPD4 | c.344T>G p.V115G | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV60021070; called by muse, mutect2, varscan2
- GHR | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.678); catalogued as rs898074355, COSV50120853; called by muse, mutect2
- GHSR | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as rs777777248, COSV53840536; called by muse, mutect2, varscan2
- GLB1L | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV55477722; called by muse, mutect2, varscan2
- GLRA3 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771115012, COSV56857256; called by muse, mutect2, varscan2
- GOLGA6B | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV69770372; called by muse, mutect2, varscan2
- GON4L | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs536637849, COSV55198320; called by muse, mutect2, varscan2
- GP2 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415494673, COSV56893778; called by muse, mutect2, varscan2
- GPC5 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.055); catalogued as rs776737101, COSV65613397; called by muse, mutect2, varscan2
- GPX5 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs756015564, COSV69079210; called by muse, mutect2, varscan2
- GRB14 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55740613; called by muse, mutect2, varscan2
- GRB14 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55740624; called by muse, mutect2, varscan2
- GRM4 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV65216077; called by muse, mutect2
- GRM6 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51443838; called by muse, mutect2, varscan2
- GSR | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV55321945; called by muse, mutect2, varscan2
- GUCY1A1 | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376624635, COSV56653848; called by muse, mutect2, varscan2
- H6PD | c.2083G>T p.A695S | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs756597678, COSV66231580; called by muse, mutect2, varscan2
- HCLS1 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57525905; called by muse, mutect2, varscan2
- HCRTR1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs767432563, COSV65485924; called by muse, mutect2, varscan2
- HDAC9 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.923); catalogued as COSV67779408; called by muse, mutect2, varscan2
- HDC | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV51068362; called by muse, mutect2, varscan2
- HDGF | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 96/370 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs945276882, COSV61975427, COSV61977111; called by muse, mutect2, varscan2
- HHIP | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.771); catalogued as COSV56836395; called by muse, varscan2
- HIF3A | c.1819C>T p.P607S (on ENST00000377670 / NM_152795.4; = p.P538S on NM_022462.4) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.043); catalogued as COSV52196952; called by muse, mutect2, varscan2
- HJV | c.1217C>T p.S406F (on ENST00000336751 / NM_213653.4; = p.S293F on NM_145277.5) | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60952693; called by muse, mutect2, varscan2
- HM13 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV59438189; called by muse, mutect2
- HNF4G | c.121C>T p.R41C (on ENST00000354370 / NM_001330561.2; = p.R88C on NM_004133.5) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62966093; called by muse, mutect2, varscan2
- HOMER1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV56528449; called by muse, mutect2, varscan2
- HSD17B3 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.015); catalogued as COSV64557799; called by muse, mutect2, varscan2
- HSF5 | c.1449A>C p.Q483H | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV60418115; called by muse, mutect2, varscan2
- HYAL4 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV56139487, COSV99033847; called by muse, mutect2, varscan2
- HYDIN | c.10649C>T p.P3550L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as COSV66880474; called by muse, mutect2, varscan2
- HYDIN | c.381+1G>A p.X127_splice | Splice Site (SNP) | VAF 31/135 reads (23%) | catalogued as COSV55489602, COSV55492220; called by muse, mutect2, varscan2
- IFNA21 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.031); catalogued as COSV66518588; called by muse, mutect2, varscan2
- IFT172 | c.3736C>A p.L1246M | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.221); catalogued as COSV53136489; called by muse, mutect2, varscan2
- IFT172 | c.1567C>T p.L523F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs1237426653, COSV53136497; called by muse, mutect2, varscan2
- IGDCC4 | c.3353G>A p.R1118K | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100732610; called by muse, mutect2, varscan2
- IGF2R | c.5204C>T p.P1735L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV63630953; called by muse, mutect2, varscan2
- IGFN1 | c.1313C>T p.S438F (on ENST00000295591 / NM_001367841.1; = p.S2895F on NM_001164586.2) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.549); catalogued as COSV55178673; called by muse, mutect2, varscan2
- IGSF22 | c.2216G>A p.R739Q (on ENST00000319338; = p.R840Q on NM_173588.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.77); catalogued as rs548983003, COSV60034448; called by muse, mutect2, varscan2
- IL37 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs867056062, COSV54492147; called by muse, mutect2, varscan2
- IL3RA | c.65-1G>A p.X22_splice | Splice Site (SNP) | VAF 53/251 reads (21%) | catalogued as COSV58432528; called by muse, mutect2, varscan2
- IMPG1 | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV64059849; called by muse, mutect2, varscan2
- INHBB | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV54678688; called by muse, mutect2, varscan2
- INPP4B | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 41/176 reads (23%) | catalogued as COSV53719120; called by muse, mutect2, varscan2
- INPP4B | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV53715106, COSV53735758; called by muse, mutect2, varscan2
- IQGAP2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV57177349; called by muse, mutect2, varscan2
- IQUB | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61240917; called by muse, mutect2
- ITCH | c.2335G>A p.E779K (on ENST00000262650 / NM_001257137.3; = p.E738K on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52934421, COSV52938118; called by muse, mutect2
- ITGA2 | c.2815C>T p.H939Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.596); catalogued as COSV56863406; called by muse, mutect2, varscan2
- ITGA7 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV99144141; called by muse, mutect2, varscan2
- ITGB3 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV71384089; called by muse, mutect2, varscan2
- ITPR3 | c.2087G>A p.W696* | Nonsense Mutation (SNP) | VAF 20/137 reads (15%) | catalogued as COSV100966806; called by muse, mutect2, varscan2
- ITPR3 | c.2088G>C p.W696C | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762211426, COSV100966807; called by muse, mutect2, varscan2
- IZUMO2 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs1248110275, COSV53230768; called by muse, mutect2, varscan2
- JAG1 | c.2229C>T p.A743= | Splice Region (SNP) | VAF 43/266 reads (16%) | catalogued as rs1568793995, COSV54759612; called by muse, mutect2, varscan2
- JAKMIP1 | c.1510C>A p.L504M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51532951; called by muse, varscan2
- JCAD | c.2586T>A p.S862R | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.14); catalogued as COSV64760739; called by muse, mutect2, varscan2
- JMJD6 | c.1168T>G p.S390A | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV100396123; called by muse, mutect2
- JMJD7 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754098815, COSV100583621; called by muse, varscan2
- KANSL3 | c.1988C>T p.P663L (on ENST00000666923 / NM_001349262.2; = p.P637L on NM_001115016.3) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV62619842; called by muse, mutect2, varscan2
- KCNJ3 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1239359925, COSV54534586, COSV54540423; called by muse, mutect2, varscan2
- KCNMA1 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as COSV54267292; called by muse, mutect2, varscan2
- KCNN3 | c.2167C>T p.P723S (on ENST00000618040 / NM_001204087.1; = p.P708S on NM_002249.6) | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.487); catalogued as rs967553480, COSV55221726; called by muse, mutect2, varscan2
- KCNQ3 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV66476268; called by muse, mutect2, varscan2
- KDM5C | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62891283; called by muse, mutect2, varscan2
- KIAA0100 | c.4370C>T p.S1457F | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV66492677; called by muse, mutect2, varscan2
- KIAA1328 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs536436186, COSV54448669; called by muse, mutect2, varscan2
- KIF4B | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV70530464; called by muse, mutect2, varscan2
- KLC2 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs140572929, COSV57583563; called by muse, mutect2, varscan2
- KLHL4 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.866); catalogued as COSV64142258; called by muse, mutect2, varscan2
- KLK8 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV51593357; called by muse, mutect2
- KRTAP5-10 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.175); catalogued as COSV100924172, COSV64795388; called by muse, mutect2, varscan2
- L3MBTL4 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99526784, COSV99530828; called by muse, mutect2, varscan2
- L3MBTL4 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 60/328 reads (18%) | catalogued as COSV53131879; called by muse, mutect2, varscan2
- LAMA3 | c.6817C>T p.L2273F (on ENST00000313654 / NM_198129.4; = p.L664F on NM_000227.6) | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52538841; called by muse, mutect2, varscan2
- LGALS12 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.958); catalogued as COSV55371348; called by muse, mutect2, varscan2
- LGALS9 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771108618, COSV56349981; called by muse, mutect2, varscan2
- LRP1 | c.4039G>A p.E1347K | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV54518660; called by muse, mutect2, varscan2
- LRP1B | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs868652515, COSV67213914; called by muse, mutect2, varscan2
- LRP6 | c.4294T>G p.L1432V | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.142); catalogued as COSV53790968; called by muse, mutect2, varscan2
- LRRC7 | c.4504G>A p.G1502R (on ENST00000651989 / NM_001370785.2; = p.G1422R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50415133; called by muse, mutect2, varscan2
- LRRTM2 | c.1268T>A p.V423E | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51223297; called by muse, mutect2, varscan2
- LYZL4 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs886913036, COSV55103923; called by muse, mutect2, varscan2
- MAGEB2 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV66781193; called by muse, mutect2, varscan2
- MAGEE2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.099); catalogued as COSV64898092, COSV64898118; called by muse, mutect2, varscan2
- MAGI1 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58335351; called by muse, mutect2, varscan2
- MAN1A2 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV62975931; called by muse, mutect2, varscan2
- MAP3K21 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762839993, COSV64045631, COSV64045793; called by muse, mutect2, varscan2
- MAP3K21 | c.2195C>T p.S732L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs750067830, COSV64042176; called by muse, mutect2, varscan2
- MAP4 | c.3211G>A p.V1071M | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV53140113; called by muse, mutect2, varscan2
- MAPK8 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV64409385; called by muse, mutect2, varscan2
- MARF1 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.755); catalogued as COSV60026285; called by muse, mutect2, varscan2
- MATR3 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63078488; called by muse, mutect2, varscan2
- MCM8 | c.1592T>G p.L531W | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54516423, COSV54516725; called by muse, mutect2, varscan2
- MCTP2 | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV59147063; called by muse, mutect2, varscan2
- MDN1 | c.11431T>C p.W3811R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65525572; called by muse, mutect2, varscan2
- ME3 | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780818020, COSV62773918; called by muse, mutect2, varscan2
- MGAT4C | c.742T>C p.Y248H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.478); catalogued as COSV100152480; called by muse, mutect2
- MPP7 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61735471; called by muse, mutect2, varscan2
- MRGPRX1 | c.956G>A p.R319K | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs267602815, COSV57108661; called by muse, varscan2
- MRGPRX1 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs1156545901, COSV57108671; called by muse, varscan2
- MRGPRX1 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100245925, COSV57108682; called by muse, mutect2, varscan2
- MRO | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 20/143 reads (14%) | catalogued as COSV56497295; called by muse, mutect2, varscan2
- MROH8 | c.1778G>A p.R593K | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.91); catalogued as COSV54122393; called by muse, mutect2, varscan2
- MROH9 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV100882708, COSV63012449; called by muse, mutect2
- MTERF3 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.188); catalogued as rs148966759, COSV54633659; called by muse, mutect2, varscan2
- MTFR2 | c.1133C>T p.T378I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as COSV63079829; called by muse, mutect2, varscan2
- MUC13 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs779195504, COSV60700508; called by muse, mutect2, varscan2
- MUC16 | c.26989A>G p.T8997A | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.047); catalogued as COSV67479772; called by muse, mutect2, varscan2
- MUC16 | c.21725C>T p.S7242F | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV67458459, COSV67472760; called by muse, mutect2, varscan2
- MUC16 | c.13699C>T p.P4567S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.246); catalogued as COSV67479781; called by muse, mutect2, varscan2
- MUC16 | c.9512C>T p.S3171L | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV67457910, COSV67479783; called by muse, mutect2, varscan2
- MUC16 | c.6439C>T p.P2147S | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs762026219, COSV67479790; called by muse, mutect2, varscan2
- MUC3A | c.7580C>T p.S2527L | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious, low confidence (0.02); catalogued as rs760213928, COSV100113802; called by muse, mutect2, varscan2
- MVB12B | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs868665716, COSV63259639; called by muse, mutect2, varscan2
- MXRA5 | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756893962, COSV54242793; called by muse, mutect2, varscan2
- MYH1 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs773084761, COSV56853005; called by mutect2, varscan2
- MYH15 | c.2023A>T p.K675* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV56315120; called by muse, mutect2, varscan2
- MYH2 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1389727909, COSV55435196; called by muse, mutect2, varscan2
- MYH7 | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs746074103, COSV62519410, COSV62521511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYNN | c.267-2A>T p.X89_splice | Splice Site (SNP) | VAF 28/157 reads (18%) | catalogued as COSV62991736; called by muse, mutect2, varscan2
- MYO18B | c.2795C>T p.S932F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59141578; called by muse, mutect2, varscan2
- NAV3 | c.6859G>A p.E2287K (on ENST00000397909 / NM_001024383.2; = p.E2265K on NM_014903.6) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57096780; called by muse, mutect2, varscan2
- NBEA | c.4879C>T p.L1627F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.969); catalogued as COSV59758802, COSV59803756; called by muse, mutect2, varscan2
- NCKAP1L | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV53202999; called by muse, mutect2, varscan2
- NEB | c.8062C>T p.H2688Y | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1352275751, COSV51437422; called by muse, mutect2, varscan2
- NEK11 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV67283753; called by muse, mutect2, varscan2
- NF1 | c.5261C>T p.S1754F (on ENST00000358273 / NM_001042492.3; = p.S1733F on NM_000267.3) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.606); catalogued as COSV55986561; called by muse, mutect2, varscan2
- NFRKB | c.1415C>T p.A472V (on ENST00000446488 / NM_001143835.2; = p.A497V on NM_006165.3) | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.218); catalogued as COSV58759269; called by muse, mutect2, varscan2
- NFYA | c.712A>G p.M238V | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV58199250; called by muse, mutect2, varscan2
- NGEF | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 23/114 reads (20%) | catalogued as COSV50934840; called by muse, mutect2, varscan2
- NLE1 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62604742; called by muse, mutect2, varscan2
- NLRP2 | c.2078C>T p.S693F | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs267605683, COSV54757704; called by muse, mutect2, varscan2
- NLRP4 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 21/100 reads (21%) | catalogued as COSV56711045; called by muse, mutect2, varscan2
- NLRP8 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); catalogued as COSV52582949; called by muse, mutect2, varscan2
- NMBR | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs745827668, COSV57802279; called by muse, mutect2
- NMD3 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV63618954; called by muse, mutect2, varscan2
- NMRK2 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs1402045635, COSV51455951; called by muse, mutect2, varscan2
- NONO | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV52135662; called by muse, mutect2, varscan2
- NOX3 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.239); catalogued as COSV50157742; called by muse, mutect2, varscan2
- NPFFR2 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs751173894, COSV58152001; called by muse, mutect2, varscan2
- NPTXR | c.1160C>T p.T387I | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV60728933; called by muse, mutect2, varscan2
- NPVF | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs759213475, COSV56061103; called by muse, mutect2, varscan2
- NR1H4 | c.328G>A p.E110K (on ENST00000551379 / NM_001206993.2; = p.E100K on NM_005123.4) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.222); catalogued as COSV51854373; called by muse, mutect2, varscan2
- NR6A1 | c.1166A>G p.Y389C (on ENST00000487099 / NM_033334.4; = p.Y384C on NM_001489.5) | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60635534; called by muse, mutect2, varscan2
- NSD3 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs764982213, COSV57620766; called by muse, mutect2, varscan2
- NUAK2 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV65681855; called by muse, mutect2, varscan2
- NUP214 | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.359); catalogued as COSV63911328; called by muse, mutect2, varscan2
- NXF1 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 25/94 reads (27%) | catalogued as rs1242043093, COSV53677747; called by muse, mutect2, varscan2
- NXF1 | c.1284C>A p.A428= | Splice Region (SNP) | VAF 24/94 reads (26%) | catalogued as COSV99585666; called by muse, mutect2, varscan2
- OBSCN | c.14838C>G p.I4946M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV52800301; called by muse, mutect2, varscan2
- OGDHL | c.2380G>A p.D794N | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.461); catalogued as COSV65103618; called by muse, mutect2, varscan2
- OR10S1 | c.434A>C p.H145P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV73342909, COSV73342946; called by muse, mutect2, varscan2
- OR13C2 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73377713; called by muse, mutect2, varscan2
- OR2A12 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV68821018; called by muse, mutect2, varscan2
- OR2A25 | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 31/182 reads (17%) | catalogued as rs866944696, COSV68716818; called by muse, mutect2, varscan2
- OR2M4 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 16/103 reads (16%) | catalogued as COSV60708985; called by muse, mutect2, varscan2
- OR2T2 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100737520; called by muse, mutect2, varscan2
- OR2Z1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as rs782472476, COSV60691691; called by muse, mutect2, varscan2
- OR4C15 | c.331C>T p.P111S (on ENST00000314644; = p.P57S on NM_001001920.2) | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as COSV58954269; called by muse, mutect2, varscan2
- OR4D10 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV73260131; called by muse, mutect2, varscan2
- OR4K17 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59648646; called by muse, mutect2, varscan2
- OR51D1 | c.124T>G p.F42V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.234); catalogued as COSV62914549; called by muse, mutect2, varscan2
- OR51V1 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV58315835; called by muse, mutect2, varscan2
- OR52N4 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100421778, COSV57891099; called by muse, mutect2, varscan2
- OR5H15 | c.823C>G p.P275A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV62948594; called by muse, mutect2, varscan2
- OR5K1 | c.684G>A p.M228I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.85); catalogued as rs867447128, COSV60303853; called by mutect2, varscan2
- OR6B1 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV68770400; called by muse, mutect2, varscan2
- OR7D4 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV58072087; called by muse, mutect2, varscan2
- OR7G3 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV59640670; called by muse, mutect2, varscan2
- OR9Q1 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.13); catalogued as COSV59043599; called by muse, mutect2, varscan2
- ORM1 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV52280238; called by muse, mutect2, varscan2
- OSBPL3 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.263); catalogued as rs1319448412, COSV57655354; called by muse, mutect2, varscan2
- OSMR | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV57088437; called by muse, mutect2, varscan2
- P3H2 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs115909080, COSV100078062, COSV60024708; called by muse, mutect2, varscan2
- PALLD | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs887419848, COSV54987533; called by muse, mutect2, varscan2
- PBX1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV63346078; called by muse, mutect2, varscan2
- PCDH18 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.42); PolyPhen probably damaging (1); catalogued as rs778145466, COSV61270295; called by muse, mutect2, varscan2
- PCDH19 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV55259448; called by muse, mutect2, varscan2
- PCDHAC1 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV53860511; called by muse, mutect2, varscan2
- PCLO | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV104415210, COSV61650521; called by muse, mutect2, varscan2
- PCNX2 | c.4270G>A p.D1424N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV50782972, COSV99266926; called by muse, mutect2
- PDE3A | c.3325C>T p.Q1109* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV62977863; called by muse, mutect2, varscan2
- PDZD2 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV56865276; called by muse, mutect2, varscan2
- PHF3 | c.719G>T p.C240F | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV50325203, COSV50327475; called by muse, mutect2, varscan2
- PIKFYVE | c.2743C>T p.P915S | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs1559129855, COSV52245388; called by muse, mutect2
- PIWIL2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1330338089, COSV63249570; called by muse, mutect2
- PKD1L1 | c.8392G>A p.E2798K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs755846293, COSV51841256; called by muse, mutect2, varscan2
- PKDCC | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99684594; called by muse, mutect2, varscan2
- PLA2R1 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759035221, COSV51782758; called by muse, varscan2
- PLCL2 | c.1006C>T p.H336Y (on ENST00000615277 / NM_001144382.2; = p.H210Y on NM_015184.5) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.424); catalogued as COSV67621802; called by muse, mutect2, varscan2
- PLEKHG6 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1477548468, COSV50605392; called by muse, mutect2
- PLPBP | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV60240011; called by muse, mutect2, varscan2
- PLXDC2 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.084); catalogued as COSV65906390; called by muse, mutect2, varscan2
- PLXNA4 | c.3508C>T p.P1170S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1425453945, COSV58106437; called by muse, mutect2, varscan2
- PLXNB1 | c.4760G>A p.R1587Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1237004004, COSV99602073; called by muse, mutect2
- PNPLA7 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV53002682; called by muse, mutect2
- PPFIA1 | c.3563G>A p.G1188E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.285); catalogued as COSV54138014; called by muse, mutect2
- PPIP5K1 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 35/377 reads (9%) | catalogued as rs373368300; called by muse, mutect2
- PPP1R36 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV53903108; called by muse, mutect2, varscan2
- PPP1R9A | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs778170394, COSV56901728; called by muse, mutect2, varscan2
- PRDM1 | c.1957C>T p.H653Y | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64845448; called by muse, mutect2, varscan2
- PRKAA2 | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV64801684; called by muse, mutect2, varscan2
- PRKCQ | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.317); catalogued as rs780846102, COSV54112580; called by muse, mutect2, varscan2
- PRSS55 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as COSV60808816; called by muse, mutect2, varscan2
- PSG5 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 66/348 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767117184, COSV61653481; called by muse, mutect2, varscan2
- PTGIS | c.858G>A p.G286= | Splice Region (SNP) | VAF 12/44 reads (27%) | catalogued as COSV54838917; called by muse, mutect2, varscan2
- PTPRB | c.4678G>A p.D1560N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs778294640, COSV54241229; called by muse, mutect2, varscan2
- PTPRB | c.3079G>A p.D1027N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.375); catalogued as COSV54247450; called by muse, mutect2, varscan2
- PTPRC | c.2638G>A p.D880N | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61406113; called by muse, mutect2, varscan2
- PTPRK | c.3566C>T p.A1189V (on ENST00000368215 / NM_001291984.2; = p.A1190V on NM_002844.4) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV63902892; called by muse, mutect2, varscan2
- PXDNL | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1049626878, COSV62493530; called by muse, mutect2, varscan2
- RAPGEF4 | c.848A>G p.K283R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.759); catalogued as COSV51403930; called by muse, mutect2, varscan2
- RBP3 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs781847641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBPMS2 | c.430G>T p.G144W | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.706); catalogued as COSV55605158; called by muse, mutect2, varscan2
- RETSAT | c.8T>A p.L3H | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV55527397; called by muse, mutect2, varscan2
- REV3L | c.3107C>A p.P1036H | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62621319; called by muse, varscan2
- REXO1 | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV50083263; called by muse, mutect2, varscan2
- RFC1 | c.2389C>T p.P797S (on ENST00000381897 / NM_001363496.2; = p.P796S on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV62900377; called by muse, mutect2, varscan2
- RGR | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.044); catalogued as COSV100812802; called by muse, mutect2
- RGS18 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV66509185, COSV99054851; called by muse, mutect2, varscan2
- RIMS1 | c.3626G>A p.G1209E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV53457285, COSV53461441; called by muse, mutect2, varscan2
- RNF152 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV57186821; called by muse, mutect2, varscan2
- RNF19A | c.1325T>C p.M442T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61994076; called by muse, mutect2, varscan2
- RORC | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV59094352; called by mutect2, varscan2
- RP1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55109499, COSV55116849; called by muse, mutect2, varscan2
- RP1 | c.4069G>A p.D1357N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV55121705; called by muse, mutect2, varscan2
- RSPH9 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64665445; called by muse, mutect2, varscan2
- RTTN | c.4424C>T p.P1475L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55348485; called by muse, mutect2, varscan2
- SACS | c.4159C>T p.P1387S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.156); catalogued as COSV66538724; called by muse, mutect2, varscan2
- SAMD3 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs774559077, COSV63713170; called by muse, mutect2, varscan2
- SCN10A | c.3220C>T p.P1074S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.089); catalogued as rs749045543, COSV71862239; called by muse, mutect2, varscan2
- SCN7A | c.4376G>A p.G1459E | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV69273239; called by muse, mutect2, varscan2
- SCN9A | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs200568743, COSV57617295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCYL1 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565072289, COSV54214071; called by muse, mutect2, varscan2
- SDAD1 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV62403356; called by muse, mutect2, varscan2
- SERPINB2 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53074330; called by muse, mutect2, varscan2
- SGCE | c.1099C>T p.L367F (on ENST00000647096; = p.L331F on NM_003919.3) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56018740, COSV56021425; called by muse, mutect2, varscan2
- SH3GL2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV66047924; called by muse, mutect2, varscan2
- SH3GL2 | c.728+1G>A p.X243_splice | Splice Site (SNP) | VAF 19/110 reads (17%) | catalogued as COSV66052644; called by muse, mutect2, varscan2
- SH3RF2 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV63040293; called by muse, mutect2, varscan2
- SHMT2 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV100196908; called by muse, mutect2, varscan2
- SHROOM3 | c.5642G>A p.R1881K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV56030203; called by muse, mutect2, varscan2
- SIAH3 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV68552525; called by muse, mutect2, varscan2
- SIDT2 | c.1702C>T p.H568Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54058733; called by muse, mutect2, varscan2
- SIGLEC10 | c.1072+1G>A p.X358_splice | Splice Site (SNP) | VAF 34/180 reads (19%) | catalogued as rs765057442, COSV59484491; called by muse, mutect2, varscan2
- SIGLECL1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV57062119; called by muse, mutect2, varscan2
- SIM1 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.151); catalogued as rs888839197, COSV53494473; called by muse, mutect2, varscan2
- SIN3A | c.2764C>G p.R922G | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV64584055; called by muse, mutect2, varscan2
- SIPA1L1 | c.3011C>T p.T1004I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV62171979; called by muse, mutect2, varscan2
- SLA2 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV53411860; called by muse, mutect2
- SLC16A12 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV57952338; called by muse, mutect2, varscan2
- SLC16A14 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV54619976; called by muse, mutect2, varscan2
- SLC16A7 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs760918584, COSV53897323; called by muse, mutect2, varscan2
- SLC22A10 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.607); catalogued as COSV60422580; called by muse, mutect2, varscan2
- SLC24A3 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV60125794; called by muse, mutect2, varscan2
- SLC26A4 | c.1341+1G>T p.X447_splice | Splice Site (SNP) | VAF 13/80 reads (16%) | catalogued as CD972381, CS062104, COSV55918296; called by muse, mutect2, varscan2
- SLC30A3 | c.323A>T p.H108L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99273386; called by muse, mutect2, varscan2
- SLC35B4 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65985091; called by muse, mutect2, varscan2
- SLC36A3 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767645275, COSV100077721, COSV100077870, COSV58857616; called by muse, mutect2, varscan2
- SLC37A2 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53523626; called by muse, mutect2
- SLC38A4 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56965388; called by muse, mutect2, varscan2
- SLC38A9 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59424944; called by muse, mutect2, varscan2
- SLC4A1 | c.1427T>G p.F476C | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV52261639; called by muse, mutect2
- SLC9A4 | c.1498C>T p.H500Y | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV54829807, COSV54832899; called by muse, mutect2, varscan2
- SLCO1C1 | c.2061A>T p.R687S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV56876243; called by muse, mutect2, varscan2
- SLIT3 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV60622487; called by muse, mutect2, varscan2
- SLITRK6 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs375069918, COSV68389890; called by muse, mutect2, varscan2
- SLX4 | c.4037C>T p.P1346L | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV53566219; called by muse, mutect2, varscan2
- SNAP91 | c.2537G>A p.G846E | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52128461; called by muse, mutect2, varscan2
- SOS2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV53567471; called by muse, mutect2, varscan2
- SP110 | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs748380337, COSV51250419; called by muse, mutect2, varscan2
- SP140 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV59452574; called by muse, mutect2, varscan2
- SPATA16 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63531079; called by muse, mutect2, varscan2
- SPATA31E1 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57793600; called by muse, mutect2, varscan2
- SPHKAP | c.4444C>T p.H1482Y | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60887529; called by muse, mutect2, varscan2
- SPICE1 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV55622967; called by muse, mutect2, varscan2
- SPTA1 | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754194243, COSV63756759; called by muse, mutect2, varscan2
- SRSF7 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.475); catalogued as COSV57447790; called by muse, mutect2, varscan2
- STARD4 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs781430123, COSV56967344; called by muse, mutect2, varscan2
- STON1 | c.2188G>A p.G730S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.998); catalogued as COSV100561357; called by muse, mutect2
- SYNPO2 | c.1604C>T p.S535F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV61114391; called by muse, mutect2, varscan2
- SYT17 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs753234680, COSV62547223; called by muse, mutect2, varscan2
- TAAR5 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs766614989, COSV57799479, COSV57799510; called by muse, mutect2, varscan2
- TAGAP | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.469); catalogued as rs866845381, COSV57852464; called by muse, mutect2
- TANC2 | c.5479T>A p.S1827T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.931); catalogued as COSV67337874; called by muse, mutect2
- TAOK1 | c.1487T>C p.L496S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55595324; called by muse, mutect2, varscan2
- TBXAS1 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54945760; called by muse, mutect2, varscan2
- TC2N | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV61747707, COSV61748625; called by muse, mutect2, varscan2
- TCEA3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.094); catalogued as COSV65840931; called by muse, mutect2, varscan2
- TCHHL1 | c.1682G>A p.S561N | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV64286637; called by muse, mutect2, varscan2
- TECTA | c.4651G>A p.E1551K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs1452561308, COSV50751217; called by muse, mutect2, varscan2
- TENM3 | c.4039G>A p.D1347N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV69314019; called by muse, mutect2, varscan2
- TENM4 | c.4525G>A p.A1509T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV99569670; called by muse, mutect2
- TENM4 | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53648679; called by muse, mutect2, varscan2
- THOC7 | c.20-1G>A p.X7_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV55733968, COSV99889675; called by muse, mutect2
- TIAM2 | c.3257C>T p.P1086L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs201303380, COSV51642669; called by muse, mutect2, varscan2
- TIMM17A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV66171388; called by muse, mutect2, varscan2
- TINAG | c.34T>C p.Y12H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.259); catalogued as COSV52512458; called by mutect2, varscan2
- TLL2 | c.1697A>C p.K566T | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1281219435, COSV63574129; called by muse, mutect2, varscan2
- TMEM132B | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as rs746605414, COSV100168718, COSV54747217; called by muse, mutect2, varscan2
- TMEM176B | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58440427; called by muse, mutect2, varscan2
- TMEM200A | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.153); catalogued as rs267600805, COSV51648937, COSV99758850; called by muse, mutect2, varscan2
- TMPRSS11F | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100678521, COSV62467875; called by muse, mutect2, varscan2
- TNRC6B | c.2283G>A p.W761* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV57301855; called by muse, mutect2
- TNXB | c.11603G>A p.R3868K (on ENST00000647633; = p.R3621K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/263 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs765951340, COSV64475849; called by muse, mutect2, varscan2
- TNXB | c.9430G>A p.V3144I (on ENST00000647633; = p.V2897I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/856 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.39); catalogued as COSV64483510; called by muse, mutect2, varscan2
- TNXB | c.8629C>T p.R2877C (on ENST00000647633; = p.R2630C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 226/1340 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs775178393, COSV64483518; called by muse, mutect2, varscan2
- TPRA1 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV56161426; called by muse, mutect2, varscan2
- TRIM15 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV64989521; called by muse, mutect2
- TRPM3 | c.691C>T p.R231C (on ENST00000357533 / NM_001366142.2; = p.R76C on NM_020952.6) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs867362714, COSV62472153; called by muse, varscan2
- TRPM7 | c.2534T>A p.F845Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV57919335; called by muse, mutect2, varscan2
- TTLL4 | c.3088C>A p.H1030N | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV51437986; called by muse, mutect2, varscan2
- TTN | c.51169G>A p.E17057K (on ENST00000591111; = p.E9633K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | PolyPhen probably damaging (0.994); catalogued as COSV60199420; called by muse, mutect2, varscan2
- TTN | c.28693G>A p.E9565K (on ENST00000591111; = p.E8638K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/157 reads (14%) | PolyPhen possibly damaging (0.737); catalogued as COSV60199470; called by muse, mutect2, varscan2
- TTN | c.19142G>A p.R6381K (on ENST00000591111; = p.R5454K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | PolyPhen benign (0); catalogued as COSV60199479; called by muse, mutect2, varscan2
- TTN | c.2815C>T p.P939S (on ENST00000591111; = p.P893S on NM_003319.4) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | PolyPhen benign (0.067); catalogued as COSV59926422; called by muse, mutect2, varscan2
- TUBD1 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV57873664; called by muse, mutect2, varscan2
- UBQLN3 | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV61164436; called by muse, mutect2, varscan2
- UBXN7 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56356701; called by muse, mutect2, varscan2
- UGT2A2 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.231); catalogued as COSV54138004; called by muse, mutect2, varscan2
- UGT2B28 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV59433264; called by muse, mutect2, varscan2
- UNC5A | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as COSV56170490; called by muse, mutect2, varscan2
- UNC79 | c.4381G>A p.E1461K (on ENST00000393151 / NM_001346218.2; = p.E1284K on NM_020818.5) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1266608031, COSV56400039; called by muse, varscan2
- USP33 | c.2212C>T p.L738F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV62470461; called by muse, mutect2, varscan2
- VIRMA | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV52588271; called by muse, mutect2, varscan2
- XKR4 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.884); catalogued as COSV59328329; called by muse, mutect2, varscan2
- XKR9 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs752979133, COSV68773220; called by muse, mutect2, varscan2
- YJU2 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV53607017; called by muse, mutect2
- YLPM1 | c.4069C>T p.R1357* | Nonsense Mutation (SNP) | VAF 34/168 reads (20%) | catalogued as rs1358992706, COSV53108618; called by muse, mutect2, varscan2
- YTHDF1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV64832670; called by muse, mutect2, varscan2
- ZBED9 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as COSV71729617; called by muse, mutect2
- ZBED9 | c.602G>A p.S201N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV71729618; called by muse, mutect2
- ZBTB18 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV100699955; called by muse, mutect2, varscan2
- ZC3H13 | c.1814G>A p.R605K | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV54459035; called by muse, varscan2
- ZC3H7B | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as rs1174279160, COSV60963438, COSV60965140; called by muse, mutect2, varscan2
- ZDHHC19 | c.177G>A p.W59* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV56349412; called by muse, mutect2, varscan2
- ZDHHC2 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs865781578, COSV50497411; called by muse, mutect2, varscan2
- ZFHX4 | c.8627A>G p.N2876S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs545519480, COSV51474377; called by muse, mutect2, varscan2
- ZIC4 | c.524G>T p.W175L | Missense Mutation (SNP) | VAF 10/263 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67173056; called by muse, mutect2
- ZNF215 | c.1435C>T p.R479* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as rs142083471; called by muse, mutect2, varscan2
- ZNF341 | c.1489C>T p.H497Y (on ENST00000375200 / NM_001282935.1; = p.H490Y on NM_032819.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61010120; called by muse, mutect2, varscan2
- ZNF347 | c.1766G>A p.G589E | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV61969872; called by muse, mutect2, varscan2
- ZNF479 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV58639626, COSV58641125; called by muse, mutect2, varscan2
- ZNF530 | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.307); catalogued as COSV60531769; called by muse, mutect2, varscan2
- ZNF536 | c.2623G>A p.G875S | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV62829073; called by muse, mutect2, varscan2
- ZNF560 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV56869284; called by muse, mutect2, varscan2
- ZNF618 | c.2659C>T p.P887S (on ENST00000374126 / NM_001318042.2; = p.P794S on NM_133374.2) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.815); catalogued as rs1323066762, COSV55925672; called by muse, mutect2, varscan2
- ZNF761 | c.688T>A p.L230I | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV61888939; called by muse, mutect2, varscan2
- ZNF761 | c.1739G>A p.C580Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs767184909, COSV61888792, COSV61888942; called by muse, mutect2, varscan2
- ZNF804A | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV56451813, COSV56453578; called by muse, mutect2, varscan2
- ZNF804B | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60831656; called by muse, mutect2, varscan2
- ZNF831 | c.4178G>A p.R1393Q | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs753837433, COSV64037136; called by muse, mutect2, varscan2
- ZNF846 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV67412311; called by muse, mutect2, varscan2
- DLGAP2 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); called by muse, mutect2
- PRAMEF18 | c.288G>A p.R96= | Splice Region (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2, varscan2
- PRAMEF20 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 72/411 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PRLHR | c.918dup p.A307Rfs*100 | Frame Shift Ins (INS) | VAF 12/80 reads (15%) | called by mutect2, pindel, varscan2
- RAI1 | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2
- SCN4A | c.704-6_706del p.X235_splice | Splice Site (DEL) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- VN1R5 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ZSCAN25 | c.1167_1199del p.Y389_K400delins* | Nonsense Mutation (DEL) | VAF 11/82 reads (13%) | called by mutect2, pindel
- ABCB11 | c.3042C>T p.F1014= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as COSV55590394; called by muse, mutect2, varscan2
- ACOX1 | c.1467C>T p.L489= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV99503218; called by muse, mutect2, varscan2
- ACSM4 | c.1041G>A p.G347= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs1411915506, COSV68068504; called by muse, mutect2, varscan2
- ADAM23 | c.381C>T p.S127= | Silent (SNP) | VAF 24/180 reads (13%) | catalogued as COSV52215034; called by muse, varscan2
- ADGRF4 | c.1065G>A p.K355= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV51954952; called by muse, mutect2, varscan2
- ADGRF4 | c.1459C>T p.L487= | Silent (SNP) | VAF 30/240 reads (13%) | catalogued as COSV51954975; called by muse, mutect2, varscan2
- AHNAK2 | c.13683C>T p.L4561= | Silent (SNP) | VAF 52/297 reads (18%) | catalogued as rs760526164, COSV60922450; called by muse, mutect2, varscan2
- AKAP9 | c.6108A>G p.E2036= (on ENST00000359028; = p.E2004= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV62352393; called by muse, mutect2, varscan2
- ALDH1A2 | c.813C>T p.I271= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV51086128; called by muse, mutect2, varscan2
- ALPP | c.1287G>A p.P429= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs760112392, COSV67397118; called by muse, mutect2, varscan2
- ANKEF1 | c.2205G>A p.L735= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV65692947; called by muse, mutect2, varscan2
- ANKRD22 | c.453C>T p.I151= | Silent (SNP) | VAF 25/151 reads (17%) | catalogued as COSV64237015; called by muse, mutect2, varscan2
- ANKRD30A | c.2640C>T p.F880= (on ENST00000611781; = p.F824= on NM_052997.2) | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs562184589, COSV100654471, COSV64606439; called by muse, mutect2, varscan2
- ANKRD54 | c.18G>A p.G6= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV53236830; called by muse, mutect2
- ANKS1A | c.561C>T p.D187= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as COSV100831955; called by muse, mutect2, varscan2
- ANKS1A | c.562C>T p.L188= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV100831957; called by muse, mutect2, varscan2
- ANXA11 | c.111C>T p.I37= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs199500343; called by muse, mutect2, varscan2
- AP1G2 | c.1929G>A p.L643= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV55338975; called by muse, mutect2, varscan2
- AP2A2 | c.855C>T p.T285= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as COSV59962312; called by muse, mutect2, varscan2
- ARHGAP25 | c.7C>T p.L3= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs1210982510, COSV54905388; called by muse, mutect2, varscan2
- ASPM | c.4194T>C p.V1398= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV54126563; called by muse, mutect2, varscan2
- ASTN2 | c.1434C>T p.F478= (on ENST00000313400 / NM_001365069.1; = p.F427= on NM_014010.5) | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs201483760, COSV57798041; called by muse, mutect2, varscan2
- ATP7B | c.1986C>T p.I662= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1157136331; called by muse, mutect2
- ATP8A1 | c.2800C>T p.L934= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV52541479; called by muse, mutect2, varscan2
- ATXN7L3 | c.148T>C p.L50= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as COSV66989400; called by muse, mutect2, varscan2
- B3GALT5 | c.426C>T p.V142= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as rs753240764, COSV58199434, COSV58199751; called by muse, mutect2, varscan2
- BLNK | c.978C>T p.P326= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV56412762; called by muse, mutect2, varscan2
- BMP15 | c.1137G>A p.K379= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV53141195; called by muse, mutect2, varscan2
- BMX | c.1989G>A p.L663= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as COSV53026286; called by muse, mutect2, varscan2
- BNC1 | c.375C>T p.L125= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV61758345; called by muse, mutect2, varscan2
- BRS3 | c.538C>T p.L180= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV65711195; called by muse, mutect2, varscan2
- BRWD3 | c.1407C>T p.F469= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1301148573, COSV64751328, COSV64752124; called by muse, mutect2
- BTBD11 | c.2712C>T p.I904= (on ENST00000280758 / NM_001018072.2; = p.I441= on NM_001017523.2) | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV55030669, COSV55039272; called by muse, mutect2
- C6orf15 | c.714C>T p.I238= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV52539038; called by muse, mutect2, varscan2
- CACNA1A | c.3912C>T p.L1304= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV64204907; called by muse, mutect2, varscan2
- CACNA1B | c.5106C>T p.L1702= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV53118492, COSV53137565; called by muse, mutect2, varscan2
- CACNG3 | c.801C>T p.L267= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs535955331, COSV50075796; called by muse, mutect2, varscan2
- CASP10 | c.1344C>T p.S448= (on ENST00000272879 / NM_032974.5; = p.S405= on NM_001230.5) | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs267599153, COSV53779539; called by muse, mutect2, varscan2
- CATSPERD | c.537G>A p.G179= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV67536039; called by muse, mutect2, varscan2
- CCDC141 | c.2889A>G p.K963= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV55377999; called by muse, mutect2, varscan2
- CCDC27 | c.609G>A p.R203= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV53901849; called by muse, mutect2, varscan2
- CCDC86 | c.177C>T p.P59= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs1340829263, COSV57125800; called by muse, mutect2, varscan2
- CCL14 | c.162G>A p.E54= (on ENST00000618404 / NM_032963.4; = p.E70= on NM_032962.4) | Silent (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- CCR6 | c.663T>C p.F221= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV59475687; called by muse, mutect2, varscan2
- CD109 | c.114C>T p.P38= | Silent (SNP) | VAF 44/159 reads (28%) | catalogued as rs201142759, COSV54653254; called by muse, varscan2
- CD163L1 | c.3555C>T p.G1185= | Silent (SNP) | VAF 43/171 reads (25%) | catalogued as COSV58020547; called by muse, mutect2, varscan2
- CDC42EP4 | c.1062C>T p.I354= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as COSV59962781; called by muse, mutect2, varscan2
- CDH22 | c.1332C>T p.I444= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV64836513; called by muse, mutect2, varscan2
- CDH22 | c.477G>A p.Q159= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV64838672; called by muse, mutect2, varscan2
- CDHR3 | c.168C>T p.I56= | Silent (SNP) | VAF 60/202 reads (30%) | catalogued as COSV58417140; called by muse, mutect2, varscan2
- CFAP58 | c.2262G>A p.K754= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV63834234, COSV63835154; called by muse, mutect2, varscan2
- CHAT | c.1560G>A p.G520= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV60320205; called by muse, mutect2, varscan2
- CHRNA4 | c.774C>T p.S258= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV64720486; called by muse, mutect2, varscan2
- CHRNA6 | c.1035C>T p.F345= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs1457178563, COSV52380408; called by muse, mutect2, varscan2
- CHST10 | c.300C>A p.L100= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV51806366; called by muse, varscan2
- CLCN7 | c.1545C>T p.I515= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1300293715, COSV51972118; called by muse, mutect2
- CLSTN3 | c.576C>T p.F192= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as COSV56938555; called by muse, mutect2, varscan2
- CMYA5 | c.8745G>A p.K2915= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV71407776; called by muse, mutect2, varscan2
- COBLL1 | c.966C>T p.T322= (on ENST00000392717; = p.T284= on NM_014900.5) | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV52072039; called by muse, mutect2, varscan2
- COCH | c.993C>T p.I331= (on ENST00000216361 / NM_001347720.1; = p.I266= on NM_004086.3) | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV53550811, COSV99363433; called by muse, mutect2, varscan2
- COL28A1 | c.261G>A p.L87= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as rs755677082, COSV68083439; called by muse, mutect2, varscan2
- COL3A1 | c.2943G>A p.G981= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as COSV58581793; called by muse, mutect2, varscan2
- CPNE2 | c.969C>T p.D323= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV51963736; called by muse, mutect2, varscan2
- CUX1 | c.432G>A p.E144= (on ENST00000292535 / NM_181552.4; = p.E155= on NM_001913.5) | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV52907393; called by muse, mutect2, varscan2
- CXCL6 | c.78C>T p.L26= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV56903183; called by muse, mutect2, varscan2
- CYP4A11 | c.1212C>T p.S404= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV60224560; called by muse, varscan2
- CYP4A11 | c.222G>A p.R74= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV60224574; called by muse, mutect2, varscan2
- DCDC1 | c.2889G>A p.R963= (on ENST00000597505 / NM_001367979.1; = p.R70= on NM_020869.3) | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1251779514, COSV60309278; called by muse, mutect2, varscan2
- DCTN1 | c.2820C>T p.G940= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as COSV62620995; called by muse, mutect2, varscan2
- DDRGK1 | c.754C>T p.L252= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV63227185; called by muse, mutect2, varscan2
- DENND1A | c.877C>T p.L293= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV65329117; called by muse, mutect2, varscan2
- DENND1B | c.1134C>T p.L378= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV52468860; called by muse, mutect2, varscan2
- DHFR2 | c.252A>T p.P84= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV58936669; called by muse, mutect2, varscan2
- DNAH10 | c.6129G>A p.A2043= (on ENST00000409039; = p.A1982= on NM_207437.3) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs767940904, COSV68997499; called by muse, mutect2, varscan2
- DNAH17 | c.3369G>A p.V1123= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV67758466; called by muse, mutect2, varscan2
- DNAH17 | c.267G>A p.K89= | Silent (SNP) | VAF 23/148 reads (16%) | catalogued as COSV67758469; called by muse, mutect2, varscan2
- DNAH7 | c.6987C>T p.I2329= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs1468424214, COSV56774995; called by muse, mutect2, varscan2
- DNAH9 | c.5886G>A p.L1962= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV52362658; called by muse, mutect2, varscan2
- DNAH9 | c.7944C>T p.I2648= | Silent (SNP) | VAF 33/201 reads (16%) | catalogued as COSV52362670; called by muse, mutect2, varscan2
- DPRX | c.516C>T p.C172= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as rs755247548, COSV64949428; called by muse, varscan2
- DSG4 | c.198G>A p.K66= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as rs868210970, COSV57394580; called by muse, mutect2
- DSP | c.7887G>A p.E2629= | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as COSV65794168; called by muse, mutect2, varscan2
- DTX4 | c.1473C>T p.S491= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV57093059; called by muse, mutect2, varscan2
- EFCAB13 | c.1557G>A p.K519= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV58950620; called by muse, mutect2, varscan2
- EFTUD2 | c.1314C>T p.I438= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as rs1272608947, COSV68183918; called by muse, mutect2, varscan2
- ESM1 | c.534G>A p.R178= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV67318553; called by muse, varscan2
- ETV6 | c.852C>T p.S284= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs761268438, COSV67149211; called by muse, mutect2, varscan2
- FAM220A | c.129A>G p.A43= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV57626949; called by muse, mutect2, varscan2
- FAM83B | c.2463C>T p.D821= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV60924508; called by muse, mutect2, varscan2
- FAM83B | c.2844G>A p.Q948= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV60924514; called by muse, mutect2, varscan2
- FAT3 | c.1179C>T p.V393= | Silent (SNP) | VAF 110/607 reads (18%) | catalogued as rs761990294, COSV53098275; called by muse, mutect2, varscan2
- FAT4 | c.9006G>A p.T3002= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs142357260; called by muse, mutect2
- FCN3 | c.567C>T p.N189= | Silent (SNP) | VAF 29/182 reads (16%) | catalogued as COSV54641964; called by muse, mutect2, varscan2
- FGA | c.2490G>A p.R830= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV57398506; called by muse, mutect2, varscan2
- FGD2 | c.180C>T p.A60= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as rs200464946; called by muse, mutect2
- FIBIN | c.69C>T p.P23= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV59413219; called by muse, mutect2, varscan2
- GABRB1 | c.1371C>T p.F457= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs917492035, COSV54991762; called by muse, mutect2, varscan2
- GALNT8 | c.69C>T p.L23= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV52899364; called by muse, varscan2
- GCKR | c.711G>A p.Q237= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV53109603; called by muse, mutect2, varscan2
- GDPD5 | c.1533C>T p.I511= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs200781096; called by muse, mutect2, varscan2
- GFRA3 | c.237G>A p.E79= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV51229748; called by muse, mutect2, varscan2
- GOLGA3 | c.636C>T p.F212= | Silent (SNP) | VAF 63/359 reads (18%) | catalogued as rs752414046, COSV52626898; called by muse, mutect2, varscan2
- GPATCH2 | c.762C>T p.L254= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1338932980, COSV65128136; called by muse, mutect2
- GPR25 | c.1041C>T p.F347= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV58498669; called by muse, mutect2
- GPR61 | c.1323C>T p.L441= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV63984169, COSV63984399; called by muse, mutect2, varscan2
- GRID2 | c.2058G>A p.A686= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs754576771, COSV56169267; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIK3 | c.2463C>T p.I821= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV66134914; called by muse, mutect2, varscan2
- GRIN2A | c.3903G>A p.E1301= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV58046073; called by muse, mutect2, varscan2
- GRM3 | c.2478C>T p.I826= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs999736107, COSV64471907; called by muse, mutect2, varscan2
- GRWD1 | c.858C>T p.I286= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV53519756; called by mutect2, varscan2
- GTPBP1 | c.807C>G p.G269= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV53286418; called by muse, mutect2, varscan2
- HCN1 | c.2568C>T p.V856= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as COSV57496197; called by muse, mutect2, varscan2
- HIVEP2 | c.5250C>T p.I1750= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV50027533; called by muse, mutect2, varscan2
- HK3 | c.1806C>T p.L602= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV52842486, COSV52845562; called by muse, mutect2, varscan2
- HOXD3 | c.1176C>T p.A392= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs760834566, COSV50882979; called by muse, mutect2
- HSD3B7 | c.891C>T p.F297= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV52680513; called by muse, mutect2, varscan2
- ICAM5 | c.1269G>A p.E423= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs747968130, COSV55748263; called by muse, mutect2, varscan2
- IDO2 | c.954G>A p.R318= (on ENST00000389060; = p.R331= on NM_194294.2) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1563444881, COSV58427279; called by muse, mutect2, varscan2
- IGDCC4 | c.3354G>A p.R1118= | Silent (SNP) | VAF 23/170 reads (14%) | catalogued as rs996800257, COSV100732606; called by muse, mutect2, varscan2
- IGHV3-13 | c.138C>T p.F46= | Silent (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- IGKV1-17 | c.126C>T p.T42= | Silent (SNP) | VAF 34/241 reads (14%) | catalogued as rs757529810; called by muse, mutect2, varscan2
- IKZF1 | c.1491C>T p.Y497= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV58789374; called by muse, mutect2
- IL1B | c.588A>G p.L196= | Silent (SNP) | VAF 44/246 reads (18%) | catalogued as COSV54522367; called by muse, varscan2
- INAVA | c.402G>A p.L134= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV66257186; called by muse, mutect2, varscan2
- INMT | c.135C>T p.L45= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV50001956; called by muse, mutect2, varscan2
- ITGA7 | c.612C>T p.A204= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99144139; called by muse, mutect2, varscan2
- ITIH5 | c.2019C>T p.I673= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV53670320; called by muse, mutect2, varscan2
- JAKMIP3 | c.255G>A p.K85= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV53826377; called by muse, mutect2, varscan2
- JMJD6 | c.1167C>T p.T389= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100396125; called by muse, mutect2
- KCNH1 | c.282C>T p.S94= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs138645753; called by muse, mutect2, varscan2
- KCNH7 | c.1788G>A p.G596= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV59805181; called by muse, mutect2, varscan2
- KCNN2 | c.528C>T p.L176= (on ENST00000264773; = p.L388= on NM_021614.4) | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV53294094; called by muse, mutect2, varscan2
- KCTD1 | c.57C>T p.I19= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as COSV58688948; called by muse, mutect2, varscan2
- KDR | c.279G>A p.V93= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs902467090, COSV55771045; called by muse, mutect2, varscan2
- KIR3DL2 | c.375C>T p.S125= | Silent (SNP) | VAF 49/300 reads (16%) | catalogued as rs1405155482; called by muse, mutect2, varscan2
- KIR3DL3 | c.1026C>T p.L342= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV52549573; called by muse, mutect2, varscan2
- KLHDC7A | c.684G>A p.V228= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV68770399; called by muse, mutect2, varscan2
- KRT34 | c.975G>A p.E325= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV67450282; called by muse, mutect2, varscan2
- L3MBTL4 | c.1482G>A p.V494= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs778689011, COSV53125275, COSV99526785; called by muse, mutect2, varscan2
- LARP1B | c.1137T>C p.H379= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV52800227; called by muse, mutect2, varscan2
- LBX1 | c.831C>T p.I277= | Silent (SNP) | VAF 50/216 reads (23%) | catalogued as rs1564695704, COSV64621977; called by muse, mutect2, varscan2
- LDLRAD4 | c.51C>T p.F17= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100761996, COSV63335286; called by muse, mutect2, varscan2
- LILRA1 | c.417G>A p.G139= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV52179664; called by muse, mutect2, varscan2
- LNPEP | c.2136A>C p.L712= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV51479588; called by muse, mutect2, varscan2
- LPA | c.2754G>A p.P918= | Silent (SNP) | VAF 25/168 reads (15%) | catalogued as rs868248275, COSV60305916; called by muse, mutect2, varscan2
- LPAR4 | c.456G>A p.R152= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV70913060; called by muse, mutect2, varscan2
- LPCAT1 | c.450C>T p.S150= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs1339257118, COSV52039634; called by muse, mutect2, varscan2
- LRRC74A | c.1248C>T p.I416= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV53611099; called by muse, mutect2, varscan2
- MAGEA4 | c.732G>A p.R244= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs1169568726, COSV52342057; called by muse, mutect2, varscan2
- MARCHF10 | c.1146G>A p.R382= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV60885161; called by muse, mutect2, varscan2
- MCM10 | c.1635T>C p.I545= (on ENST00000484800 / NM_182751.3; = p.I544= on NM_018518.5) | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV66335629; called by muse, mutect2, varscan2
- MCTP2 | c.2385C>T p.F795= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV63295371; called by muse, mutect2, varscan2
- MGAT4C | c.741T>C p.T247= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100152482; called by muse, mutect2
- MICAL1 | c.1971G>A p.K657= | Silent (SNP) | VAF 27/181 reads (15%) | catalogued as COSV57806303; called by muse, mutect2, varscan2
- MUC16 | c.34893G>A p.V11631= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs1339424862, COSV67454784, COSV67458678; called by muse, mutect2, varscan2
- MUC16 | c.30726G>A p.G10242= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs375041584, COSV67479769; called by muse, mutect2, varscan2
- MUC16 | c.30156A>C p.S10052= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV67479770; called by muse, mutect2, varscan2
- MUC16 | c.16590C>T p.S5530= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs769999921, COSV67479779; called by muse, mutect2
- MUC16 | c.7764A>G p.E2588= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs772751330, COSV67479786; called by muse, mutect2, varscan2
- MYH11 | c.2307C>T p.F769= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1282852123, COSV55561668; called by muse, mutect2, varscan2
- MYH8 | c.4260G>A p.T1420= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs569728381, COSV67960211; called by muse, mutect2, varscan2
- MYO3B | c.303G>A p.Q101= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV58710077; called by muse, mutect2, varscan2
- MYOCD | c.1761G>A p.V587= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV58507657; called by muse, mutect2, varscan2
- NAA11 | c.132C>T p.I44= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV54515200; called by muse, mutect2, varscan2
- NAALAD2 | c.1578T>G p.R526= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV58963497; called by muse, mutect2, varscan2
- NEU3 | c.1374C>T p.F458= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV53637899, COSV99579502; called by muse, mutect2, varscan2
- NLRP8 | c.486C>T p.F162= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV52590808; called by muse, mutect2, varscan2
- NLRP8 | c.1098C>T p.F366= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV52590827; called by muse, mutect2, varscan2
- NMBR | c.1017C>T p.L339= | Silent (SNP) | VAF 37/119 reads (31%) | catalogued as COSV57802269; called by muse, mutect2, varscan2
- NRK | c.3546C>T p.P1182= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV54601711, COSV99688043; called by muse, mutect2, varscan2
- NRXN1 | c.678G>C p.G226= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV68028504; called by muse, mutect2, varscan2
- NT5C1B | c.642G>A p.E214= (on ENST00000359846 / NM_001199086.2; = p.E154= on NM_033253.4) | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV58397552; called by muse, mutect2
- NUP155 | c.1017T>C p.F339= (on ENST00000231498 / NM_153485.3; = p.F280= on NM_004298.4) | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV51532400; called by muse, mutect2
- NWD1 | c.4234C>T p.L1412= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as rs769324349, COSV60346777; called by muse, varscan2
- OBSCN | c.22281G>A p.R7427= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV62873839; called by muse, mutect2, varscan2
- OR10H1 | c.93C>T p.F31= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV58472411; called by muse, mutect2, varscan2
- OR10X1 | c.552C>T p.F184= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs139262126; called by muse, mutect2, varscan2
- OR13C5 | c.618C>T p.F206= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as rs562361938, COSV66164905; called by muse, mutect2, varscan2
- OR1F1 | c.498C>T p.L166= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV58961806; called by muse, mutect2, varscan2
- OR1F1 | c.891G>A p.L297= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV58961814; called by muse, mutect2, varscan2
- OR1S2 | c.171C>T p.L57= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV56919929; called by muse, mutect2, varscan2
- OR2B11 | c.876C>T p.F292= | Silent (SNP) | VAF 36/224 reads (16%) | catalogued as COSV59510811; called by muse, mutect2
- OR4A15 | c.609G>A p.A203= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs141225150, COSV100123917; called by muse, mutect2, varscan2
- OR4K2 | c.336C>T p.I112= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs754020790, COSV53848253; called by muse, mutect2, varscan2
- OR51F1 | c.222G>A p.R74= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV58579370, COSV58580239; called by muse, mutect2, varscan2
- OR52B4 | c.735C>T p.S245= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV68769241; called by muse, mutect2, varscan2
- OR6C75 | c.459C>T p.I153= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV58553024, COSV58553674; called by muse, mutect2, varscan2
- OR7G2 | c.294G>A p.T98= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs377637744; called by muse, mutect2, varscan2
- OR8G5 | c.903G>A p.L301= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100422166; called by muse, mutect2, varscan2
- OR8J1 | c.702G>A p.R234= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV57316798; called by muse, mutect2
- OTOF | c.1872G>A p.R624= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as COSV55508427; called by muse, mutect2, varscan2
147 further variants in this file (0 protein-altering or splice-affecting, 119 silent, 28 other) are not listed here.
